Gene-level copy-number profile of tumor specimen ALCH-B0AR-TTP1-A from ALCHEMIST case ALCH-B0AR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.1 years (29,628 days).
Specimen ALCH-B0AR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df374a8c-18f9-4c42-ba99-5fd2448e17f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0AR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/8b481107-e8ce-41cd-aba2-da22a169e4dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 10,485; copy number 2: 34,762; copy number 3: 9,135; copy number 4: 3,375; copy number 5: 92; copy number 6: 10; copy number 7: 36; copy number 8: 165; copy number 9: 179; copy number 10: 100; copy number 13: 38.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr9:41,340,823–41,648,035, 8 genes: CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5.
- chr9:64,810,865–64,836,341, 2 genes: BNIP3P4, AL359955.1.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr18:10,893,617–10,908,783, 1 gene (within-gene range 0–1): AP005120.1.
- chr19:30,665,274–30,668,647, 1 gene (within-gene range 0–1): AC011478.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 620 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,936,581–248,937,043, 1 gene, copy number 8: RPL23AP25.
- chr4:53,377,641–57,724,655, 95 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr7:996,986–2,844,308, 49 genes, copy number 5: C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1.
- chr19:32,830,509–39,270,188, 309 genes, copy number 5–13 (broad region; genes not listed).
- chr19:52,702,813–53,824,394, 118 genes, copy number 9 (broad region; genes not listed).
- chr20:51,386,957–56,005,519, 48 genes, copy number 8–10: NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4.

Autosomal genes at a single copy (total copy number 1): 10,343. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
